Gene-level copy-number profile of tumor specimen TCGA-14-0740-01B from TCGA case TCGA-14-0740, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.2 years (25,627 days).
Specimen TCGA-14-0740-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.623fa1f7-059e-4b8a-ba63-5b55b0086bed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-0740-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fcd7b272-cfe0-4a10-a57c-fd49e593e01c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 9,443; copy number 3: 13,967; copy number 4: 31,564; copy number 5: 4,405; copy number 6: 172; copy number 7: 34; copy number 8: 19; copy number 9: 28; copy number 10: 32; copy number 14: 12; copy number 18: 99; copy number 23: 11; copy number 27: 18; copy number 28: 8; copy number 35: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-0740-01B-01D-1842-01): tumor purity 0.89, ploidy 3.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 214 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:7,922,425–17,817,798, 156 genes, copy number 9–35 (broad region; genes not listed).
- chr9:37,002,697–37,358,149, 9 genes, copy number 18 (within-gene range 1–18): AL161781.2, AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1.
- chr9:86,944,362–87,002,033, 2 genes, copy number 18 (within-gene range 2–18): GAS1, GAS1RR.
- chr9:104,970,593–104,991,818, 1 gene, copy number 18 (within-gene range 2–18): CT70.
- chr10:47,300,197–47,327,588, 2 genes, copy number 9 (within-gene range 2–9): GDF10, GDF2.
- chr10:69,432,972–69,633,596, 12 genes, copy number 9: ATP5MC1P7, TSPAN15, AC016821.1, TMEM256P1, NEUROG3, AL450311.1, MTATP6P23, MTCO2P23, MTCO1P23, MTND2P15, MTND1P20, FAM241B.
- chr10:90,402,521–92,030,325, 29 genes, copy number 10: LINC02653, AL391704.1, AL391704.2, AL390862.1, HTR7, RPP30, Y_RNA, ANKRD1, RNU6-740P, AL365434.1, AL365434.2, LINC00502, DDX18P6, NUDT9P1, AL731553.1, PCGF5, HECTD2, AL161798.1, RPS27P1, PPP1R3C, GAPDHP28, FAF2P1, TNKS2-AS1, TNKS2, SRP9P1, AL359198.2, FGFBP3, AL359198.1, BTAF1.
- chr10:92,076,242–92,138,370, 3 genes, copy number 10: AL365398.1, SDHCP2, EIF4A1P8.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
